CCDI case PBBUKA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/e9976243-37cf-4006-8e65-512ca7471f69

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 3.3 years (1,194 days).

Biospecimens (3 samples)
- Sample 0DHKP1: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: FFPE.
- Sample 0DHKPT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHKQB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
